Somatic mutation profile of tumor specimen ASCProject_0011_T1_WES (aliquot ASCProject_0011_T1_WES_1) from CMI case ASCProject_0011, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.0 years (12,414 days).
Specimen ASCProject_0011_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49fdc3f4-fd48-4baf-9f46-1c767cf78c81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0011_SALIVA (Saliva), aliquot ASCProject_0011_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad5092c5-fb4f-4959-b1a4-d7c3c4e70467

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, 3'Flank 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- C17orf78 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs761844357; called by muse, varscan2
- GPR162 | c.1642G>A p.V548I (on ENST00000311268 / NM_019858.2; = p.V264I on NM_014449.2) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs375828119; called by muse, mutect2, varscan2
- LMX1B | c.1171C>T p.R391W (on ENST00000373474 / NM_001174147.2; = p.R384W on NM_002316.4) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs141496559; called by muse, mutect2
- NPHP1 | c.557C>G p.P186R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV57206817; called by muse, mutect2
- SAG | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101300721; called by muse, mutect2, varscan2
- COL15A1 | c.1795T>C p.W599R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.445); called by muse, varscan2
- GNA13 | c.1031A>G p.H344R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2
- HDAC4 | c.2954C>T p.S985L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KIF18A | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- P4HA1 | c.1353_1354del p.T452Mfs*7 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PCDHGC4 | c.2208A>C p.R736S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SLC24A3 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, varscan2
- SSMEM1 | c.521A>G p.D174G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- CFAP46 | c.624C>T p.H208= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs142414152; called by muse, mutect2, varscan2
- MID1 | c.453G>A p.P151= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs771156478; called by muse, mutect2, varscan2
- TNXB | c.2673C>T p.D891= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs767734386; called by muse, mutect2, varscan2
- CRIP3 | chr6:43305811 G>A | 3'Flank (SNP) | VAF 7/23 reads (30%) | catalogued as rs377417533; called by muse, mutect2, varscan2
- VAC14 | c.1160+3260T>C | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as rs978599934; called by muse, varscan2
